Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AD8S, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AD8S-TTP1-A (Primary Tumor).

[page 1 of 16]
Results

PATHOLOGY (Order [REDACTED])

Collection Information

Collected: [REDACTED] +19

Specimen Type
Other, specify [35]

Result Date - [REDACTED] +35

Component Results

Component
PATHOLOGY/CYTOLOGY REPORT (Final)

Patient: [REDACTED] Accn No: [REDACTED]
MRN: [REDACTED] Collected: [REDACTED] +19

SURGICAL PATHOLOGY FINAL REPORT

Diagnosis

A. Liver, left lobe, needle core biopsy
- poorly differentiated adenocarcinoma consistent with metastasis from
patient's stomach primary (see [REDACTED], see comment.

Pathologist Comment

The malignant cells are similar to those seen on previous stomach biopsy
[REDACTED]

The malignant cells have the following immunohistochemical staining
characteristics: Negative for Her-2/Neu, CK7, CK20, CD45, P63, CK 5/6,
CD20 and HSA. The immunohistochemical staining characteristics are
noncontributory. [REDACTED] An additional panel of immunohistochemical
stains reveals the malignant cells to be negative for HMB-45, Melan-A, S-
100 and panmelanoma cocktail. [REDACTED]

[REDACTED] They
adenocarcinoma. Please see a copy of their report.

Clinical Information

[page 2 of 16]
Masses, GI malignancy.

Specimen Source

A Liver, LEFT LOBE

Microscopic Description

Microscopic examination was performed.

Gross Description

Part A. Submitted in a container of formalin labelled [REDACTED] - left lobe, liver" are multiple tan-pink needle core biopsy fragments ranging in size from 0.3 to 0.6 cm. The specimen is submitted entirely in A1 with

IPX

stains ordered.

Additional Comment

IMMUNOHISTOCHEMISTRY

The performance characteristics of all immunohistochemical stains cited in this report were determined by the Diagnostic Immunohistochemistry Laboratory of [REDACTED] in compliance with CLIA'88 regulations. Some of these tests rely on the use of "analyte specific reagents" and are subject to specific labeling requirements by the FDA.

This testing was developed by the Diagnostic Immunohistochemistry Laboratory of [REDACTED]. It has not been cleared or approved by the FDA. The FDA has determined that such clearance or approval is not necessary.

SURGICAL PATHOLOGY PRELIMINARY REPORT

Specimen Source

A Liver, LEFT LOBE

Preliminary Diagnosis/Comment

Liver, left lobe, needle core biopsy
- malignant neoplasm
- final diagnosis to follow special stains.

Specimen Source

A Liver, LEFT LOBE

Preliminary Diagnosis/Comment

A. Liver, needle core biopsy - poorly differentiated malignant neoplasm -
final diagnosis to follow consultation from [REDACTED]

[page 3 of 16]
6/6

Pathology Report

Path Review of Outside Specimen

Clinic Number:

Patient Name:

Date of Birth:

Order Number:

Age: 76) Gender: M

Accession #:

Received Date:

Report Signed:

+26

Referring Physician:

Final Diagnosis:

+0

Stomach, mass, endoscopic biopsy

Poorly differentiated adenocarcinoma.

Submitted immunohistochemical stains show that the tumor cells are negative for p63, CK5/6, CD20, CD3 and CK20. Additional immunohistochemical stains were performed and the tumor cells are positive for AE1/AE3 and OSCAR; focally positive for CK7 and synaptophysin; and negative for chromogranin. CDX2 immunostain is weakly positive within isolated tumor cells. Mucicarmine stain is negative.

+19

Liver, masses, needle biopsy

Involved by poorly differentiated adenocarcinoma, consistent with metastasis from the patient's known stomach primary.

Submitted immunohistochemical stains show that the tumor cells are negative for S-100, pan melanoma, CK7, CK20, CD20, CK5/6, p63, Hepar-1, Melan A and HMB-45. Additional immunohistochemical stains were performed and the tumor cells are positive for AE1/AE3 and OSCAR; focally positive for CDX2. Mucicarmine stain is negative (see comment).

Seen in consultation with

Diagnosis Comment:

[page 4 of 16]
Report Continued

I completely agree with your impression on this case. I also shared this case with [REDACTED] who shares my interest in GI pathology and in our opinion, the stomach biopsy shows a poorly differentiated adenocarcinoma. The liver biopsy also shows a morphologically similar tumor, consistent with metastasis from the patient's gastric adenocarcinoma.

Material Received:

stomach - 12 slides [REDACTED]

liver - 19 slides [REDACTED]

1 block [REDACTED] +1

1 block [REDACTED] +1

Specimen Description:

A: Consult Material

Slide Disposition:

Returned 31 slides, 2 blocks and 27 slides made here [REDACTED] +35

[page 5 of 16]
Patient Name	Patient ID	Age 76	Gender M	Order #
Ordering Phys				DOB
Collected	Account Information			Report Notes
Printed				

Test	Flag Results	Unit	Reference Value	Perform Site
Surgical Pathology Consultation		REPORTED		
Accession Number			+34	
Referring Pathologist/Physician				
Ref Path/Phys Address				
Specimen:				
A: Consult Material				
Material:				
stomach - 12 slide				
liver - 19 slides				
1 block	+1			
1 block	+1			
SLIDE DISPOSITION:				
Returned 31 slides, 2 blocks and 17 slides made here			+35	
Final Diagnosis:				
Stomach, mass, endoscopic biopsy	Poorly differentiated adenocarcinoma.	Poorly	+0	
Submitted immunohistochemical stains show that the tumor cells are negative for p63, CK5/6, CD20, CD3 and CK20. Additional immunohistochemical stains were performed and the tumor cells are positive for AE1/AE3 and OSCAR; focally positive for CK7 and synaptophysin; and negative for chromogranin. CDX2 immunostain is weakly positive within isolated tumor cells. Mucicarmine stain is negative.				
Liver, masses, needle biopsy	Involved by		+19	
poorly differentiated adenocarcinoma, consistent with metastasis from the patient's known stomach primary.				
Submitted immunohistochemical stains show that the tumor cells are negative for S-100, pan melanoma, CK7, CK20, CD20, CK5/6, p63, Hepar-1, Melan A and HMB-45. Additional immunohistochemical stains were performed and the tumor cells are positive for AE1/AE3 and OSCAR; focally positive for CDX2. Mucicarmine stain is negative (see comment).				
Seen in consultation with				
Comment:	I completely agree with your impression on this case. I also shared this case with who shares my interest in GI pathology and in our opinion, the stomach biopsy shows a poorly differentiated adenocarcinoma. The liver biopsy also shows a morphologically			

Performing Site Legend on Last Page of Report

Patient Name	Collection Date and Time	Report Status
	+19	Final
Page 1 of 2		>> Continued on Next Page >>

[page 6 of 16]
Laboratory Service Report

Patient Name	Patient ID	Age	Gender	Order #
		76	M	
Ordering Phys				DOB
	Account Information			Report Notes
Collected				
Printed				
+19				

similar tumor, consistent with metastasis from the patient's gastric adenocarcinoma.

Test	Flag Results	Unit	Reference Value	Perform Site*
similar tumor, consistent with metastasis from the patient's gastric adenocarcinoma.				
Keratin (AE1/AE3), Immunostain	Performed	REPORTED		+34
Mucicarmine Stain for Mucin		REPORTED		+34
Mayer's Mucicarmine ST for Mucin	Performed			
Chromogranin, Immunostain	Performed	REPORTED		+34
Synaptophysin, Immunostain	Performed	REPORTED		+34
CDX2, Immunostain	Performed	REPORTED		+34
Keratin 7 (KRT7), Immunostain	Performed	REPORTED		+34
Keratin (OSCAR), Immunostain	Performed	REPORTED		+34

* Performing Site:

Patient Name	Collection Date and Time	Report Status
	+19	Final
Page 2 of 2		** End of Report **

[page 7 of 16]
Patient Name
Date of Birth
Gender
Medical Record #
Master Accession
Case No
Concurrent Cases

Client Name
Client ID#
Ordering Physician
Treating Physician
Date/Time Collected
Date/Time Received

+0

+22
cc:

HER-2/neu by Fluorescence in Situ Hybridization

Stomach Tissue **UNAMPLIFIED - 1.3**

KARYOTYPE: nuc ish 17cen(D17Z1x1-3), 17q11.2(HER-2x2-6)[20]

Stomach

Result	UNAMPLIFIED
# of cells examined	20
# of fields examined	5
HER-2/CEP17 Ratio	1.3
Total HER-2 Count	61
Average HER-2 count	2.6
Max HER-2 Count	6
Total CEP-17 Count	40
Average CEP-17 Count	2.0

10% Neutral Buffered Formalin: Yes
Fixation Duration > 6 and < 48 Hours: Not Given

REFERENCE RANGE	
Negative (UnAmplified)	HER-2/CEP-17 ratio < 1.8
Equivocal	HER-2/CEP-17 ratio 1.8 - 2.2
Positive (Amplified)	HER-2/CEP-17 ratio > 2.2

Comment: The HER-2 FISH test is designed to detect amplification of the HER-2/neu gene via fluorescence in situ hybridization (FISH) in formalin-fixed, paraffin-embedded (FFPE) human breast cancer tissue specimens and FFPE specimens from patients with metastatic gastric or gastroesophageal junction adenocarcinoma. The HER2 FISH test is indicated as an aid in the assessment of patients for whom Herceptin® (trastuzumab) treatment is being considered (see Herceptin® package insert).

For breast cancer patients, results from the HER2 FISH testing of HER2 gene amplification are intended for use as an adjunct to the clinicopathologic information currently used for estimating prognosis in stage II, node-positive breast cancer patients.

Methodology:

[page 8 of 16]
Patient Name
Date of Birth
Gender
Medical Record #
Master Accession
Case No
Concurrent Cases

Client Name
Client ID#
Ordering Physician
Treating Physician
Date/Time Collected
Date/Time Received

+0
+22

HER-2 gene amplification was assessed utilizing the PathVysion assay (Vysis Corp., Downers Grove, Illinois). The identification probes for the HER-2 (SpectrumOrange) and alpha satellite DNA sequence at the centromeric region of chromosome 17 (SpectrumGreen) were hybridized according to the manufacturer's guidelines. At least twenty non-overlapping nuclei containing at least one orange and one green signal were enumerated. The ratio of orange signals (HER-2 gene) to green signals (chromosome 17) was calculated. A ratio greater than or equal to 2.0 is considered as amplified based on the FDA approval in this kit. The CAP HER-2 consensus conference 2002 suggested that a ratio of 1.8-2.2 be considered as borderline.

Intended Use:

The PathVysion HER-2 DNA Probe Kit (PathVysion Kit) is designed to detect amplification of the HER-2/neu gene via fluorescence in situ hybridization (FISH) in formalin-fixed, paraffin-embedded human breast cancer tissue specimens. Results from the PathVysion Kit are intended for use as an adjunct to existing clinical and pathological information currently used as prognostic factors in stage II, node-positive breast cancer patients. The PathVysion Kit is further indicated as an aid to predict disease-free and overall survival in patients with stage II, node-positive breast cancer treated with adjuvant cyclophosphamide, doxorubicin, and 5-fluorouracil (CAF) chemotherapy. The PathVysion Kit is indicated as an aid in the assessment of patients for whom HERCEPTIN® (trastuzumab) treatment is being considered.

[page 9 of 16]
Results

PATHOLOGY (Order

Collection Information

Collected: +0

Specimen Type
Other, specify [35]

Result Date +32

Component Results

Component
PATHOLOGY/CYTOLOGY REPORT (Final)

Patient:
MRN:

Accn No:
Collected: +0

SURGICAL PATHOLOGY FINAL REPORT

Diagnosis

A. Stomach, biopsies
- fragment of squamous and gastric mucosa with single fragment of degenerate atypical cells and ulcer exudate consistent with invasive neoplasm, see comment.

Pathologist Comment

The tumor is degenerate, likely accounting for lack of immunoreactivity. Additional tissue should be considered if clinically indicated.

Clinical Information

Mass.

Specimen Source

A Stomach

Microscopic Description

Sections show squamous and gastric glandular mucosa. A single fragment is composed of an ulcer exudate and necrotic apparent invasive malignant tumor. No specific staining is seen with squamous markers p63 or CK5/6,

[page 10 of 16]
adenocarcinoma markers CK7 and CK20, or the B cell marker CD20.

Gross Description

Part A. Submitted in a container of formalin labelled [REDACTED], #1 gastric mass" are six tan pink tissue fragments ranging in size from 0.2 to 0.5 cm. The tissue is submitted entirely in A1.

SURGICAL PATHOLOGY ADDENDUM REPORT

Discussion

+21

A tumor block was submitted to [REDACTED] for determination of HER-2 by fluorescence in situ hybridization (FISH). In this analysis, the HER-2/CEP17 ratio is determined. A ratio less than 1.8 is considered unamplified (negative), while a ratio greater than 2.2

is considered amplified (positive). A ratio of 1.8 to 2.2 is considered equivocal.

Diagnosis

RESULTS OF HER-2 BY FISH: UNAMPLIFIED 1.3 (NEGATIVE)

NOTE: Ancillary laboratory reports are scanned to the patient's electronic health record. To view, click "Scan" located under "Results" header immediately following this pathology report.

SURGICAL PATHOLOGY PRELIMINARY REPORT

Specimen Source

Stomach

Preliminary Diagnosis/Comment

Poorly differentiated neoplasm. Initial markers not diagnostic. Additional markers pending.

Results

Scan of [REDACTED] +27

Lab and Collection

PATHOLOGY (Order [REDACTED]) Lab and Collection Information

+0

Result History

PATHOLOGY (Order [REDACTED]) Order Result History Report

+32

[page 11 of 16]
IMAGING SERVICES

Exam Date/Time: -2

Phone #:

MRN:

Sex:
Male

Account #:

Accession #:

Emergency

Primary Care Provider:

Ordering Provider:

Final - CT ABDOMEN PELVIS W CONTRAST

Reason for Exam: Abdominal Pain LUQ; Abdominal Pain LLQ

Diagnosis:

INTERPRETATION

Exam: CT ABDOMEN PELVIS W CONTRAST

Date/Time of Exam: -2

Time printed on images is

Reason For Exam: Abdominal Pain LUQ, Abdominal Pain LLQ.

Comparison: No previous scan.

Technique: CT of the abdomen and pelvis was performed following the administration of intravenous contrast.

Contrast: oral contrast and 100 mL of Optiray-240 IV contrast

Findings:

1. There is a small amount of contrast material within the esophagus, probably due to esophageal dysmotility. The gastroesophageal junction is abnormally thick and the gastric lumen is indented. No history of fundoplication is available. There are no identified surgical clips. Findings are worrisome for a mass.

2. There are approximately seven large hepatic masses. One in the anterior mid to lower right lobe on series two slice 27 and is 4.2 x 4.6 cm. One superior to the porta hepatis is 4.6 x 6.9 cm on slice 18. The liver has a few tiny calcified probable granulomas.

3. The gallbladder, pancreas, and right adrenal are normal.

4. There are calcifications in the spleen consistent with old histoplasmosis.

5. The left adrenal is hypertrophied without visible nodule.

6. The lateral mid right kidney has focal cortical atrophy. There is focal cortical atrophy or mild lobulation of the posterior left renal upper pole. The kidneys have mild perinephric stranding without hydronephrosis. There is no ureteral stone. The urinary bladder appears normal.

7. The prostate is enlarged, 6.1 cm in diameter. Borderline large is 5 cm. The prostate has minimal calcifications.

8. There is no free fluid, free air, or lymphadenopathy. The small bowel is not distended. There is no small bowel malrotation.

9. There 3 or 4 ventral hernias. There is a midline ventral hernia or two adjacent hernias, approximately 4 cm superior to the umbilicus containing two separate small bowel loops. A hernia to left of midline approximately 7 cm superior to the umbilicus contains a single

[page 12 of 16]
loop of small bowel. A hernia to the left of midline approximately 4 cm superior to the umbilicus contains a loop of small bowel.

10. There is an ileocolonic anastomosis. The descending colon and sigmoid have diverticulosis without diverticulitis. There are a few scattered diverticula within the transverse colon.
11. The abdominal aorta contains calcification without aneurysm. There is calcification at the origins of the major abdominal branches. There are coronary artery calcifications.
12. The lung bases have peripheral and mild platelike atelectasis.
13. There is no free air, free fluid, or lymphadenopathy.
14. Some of the posterior left ribs have old fractures. The spine has degenerative changes.

IMPRESSION

Impression: Hepatic masses, probably metastatic malignancy. Right hemicolectomy. Either fundoplication or mass at the gastroesophageal junction. Mildly enlarged prostate. Diverticulosis. Ventral hernias containing small bowel loops, without visible obstruction. Peripheral and platelike atelectasis in lung bases. Chronic appearing additional findings.

[page 13 of 16]
IMAGING SERVICES

Exam Date/Time: [REDACTED] +564

Phone #: [REDACTED] MRN: [REDACTED]

Sex:

Account #: [REDACTED]

Male

Accession #: [REDACTED]

Performing Department: [REDACTED]

Outpatient

Primary Care Provider: [REDACTED]

Ordering Provider: [REDACTED]

Authorizing Provider: [REDACTED]

Final - CT CHEST ABDOMEN PELVIS WO CONTRAST

Reason for Exam:

Diagnosis: Malignant neoplasm of stomach, unspecified site
Metastasis to liver

INTERPRETATION

IMPRESSION

IMPRESSION: See report below.

Exam: CT CHEST ABDOMEN PELVIS WO CONTRAST

Date/Time of Exam: [REDACTED] +564

Reason For Exam: Malignant neoplasm of stomach, unspecified site.

Axial sections are obtained through the chest, abdomen, and pelvis with oral contrast. Intravenous contrast was not utilized. Most recent comparison study is a CT chest, abdomen and pelvis noncontrast from [REDACTED] +438

Findings:

Chest:

Lungs show some calcified granulomatous disease but no noncalcified masses or nodules. No pleural fluid is seen. Trachea and major airways are clear. Lack of intravenous contrast makes evaluation for hilar and mediastinal adenopathy somewhat limited but no obvious lesions are seen. No abnormal axillary lymph nodes are seen. Chest wall is intact.

Abdomen/pelvis:

No free fluid or gas is seen in the peritoneal cavity. Peritoneal wall musculature shows umbilical hernia with a loop of bowel herniated through it similar to prior exam. Fat-containing hernia just superior to this and to the left is again seen and shows no bowel herniation. No new hernias are identified. Bowel loops show some diverticular disease in the sigmoid colon but no active inflammation. Retroperitoneum shows normally sized vascular structures and no definite mass lesions.

Liver shows some calcified granulomas. Lack of intravenous contrast

[page 14 of 16]
makes evaluation for a solid mass lesion somewhat limited. Prior noted lesion in the dome of the right lobe of the liver is not definitively seen on today's study. On prior exams, there also was a lesion described superiorly in the left lobe of the liver which again is not identified on today's study. Gallbladder and biliary system are normal. Spleen shows some granulomas. Pancreas, adrenals, and kidneys are normal.

in the pelvis prostate appears to be diffusely enlarged. Bladder shows some wall thickening but is relatively nondistended. No pelvic adenopathy is seen.

Bony windows show some degenerative osteophytic change in the lumbar spine.

Impression:

Lack of intravenous contrast limits evaluation for neoplastic processes but no definite enlarged lymph nodes or masses are seen. Prior noted liver lesions are difficult to ascertain on today's study. If further work is required, correlation with a PET-CT scan may be more useful than noncontrast CT scan.

Other incidental findings are as described above.

[page 15 of 16]
IMAGING SERVICES

Exam Date/Time:	+1219	Phone #:	MRN:
Sex:	Male	Account #:	
Pt. Class:	Outpatient		
Primary Care Provider:			

Final - CT CHEST ABDOMEN PELVIS WO CONT

Reason for Exam:

Diagnosis: Metastasis to liver [REDACTED]
Malignant neoplasm of stomach, unspecified site [REDACTED]

INTERPRETATION

IMPRESSION

IMPRESSION: See report below.

Exam: CT CHEST ABDOMEN PELVIS WO CONT

Date/Time of Exam: [REDACTED] +1219

Reason For Exam: Metastasis to liver.

Technique: CT of the chest, abdomen, and pelvis was performed without the administration of intravenous contrast. Oral and rectal contrast only.

+1012 Findings: Comparison to prior CT chest, abdomen and pelvis performed on [REDACTED]. Right-sided port infusion catheter remains in place. Biapical subpleural reticulation most likely represents scarring and is unchanged. Stable calcified pulmonary granulomata. Stable areas of bilateral pulmonary scarring and/or atelectasis. A few scattered noncalcified pulmonary micronodules are stable. There is a small sliding hiatal hernia. There are coronary artery calcifications noted. There is no evidence of hilar, axillary or mediastinal lymph node enlargement given limitation of noncontrast technique.

9 mm hypodensity subcapsular aspect inferior right hepatic lobe medially series 2 image 73 is stable. A few scattered calcified hepatic granulomata are also noted. There are gallstones again seen. There is no evidence of biliary dilatation. The spleen and pancreas are unremarkable. Adrenal glands are within normal limits. There is asymmetric right renal cortical scarring. Left kidney demonstrates minimal scar. Anterior abdominal wall hernias variably contain fat and nonobstructive small bowel loops are again seen. Colonic diverticulosis is present, most severe at the level of sigmoid colon with no evidence of acute inflammatory change. Prostate is enlarged. Urinary bladder wall is within normal limits. Small bilateral fat-containing inguinal hernias. There is no ascites, adenopathy or aneurysm. There is mild to moderate degenerative change noted in the spine. Interval appearance of healing fracture of the left superior inferior pubic rami as well as of the right sacrum. No focal

[page 16 of 16]
underlying pathologic lesion is visualized.

Impression: No strong evidence of metastatic disease. Stable nonspecific subcentimeter hepatic lesion as well as multiple minor findings including colonic diverticulosis, prostatomegaly, ventral hernias. Interval appearance of healing fractures of left pubic rami and right sacrum as described on MRI of [REDACTED] +1057

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3a57ffb7-e2bc-44f4-bd46-b9b079c7b7a9 (ER0342 ER-AD8S Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).